Somatic mutation profile of tumor specimen TCGA-EJ-5509-01A (aliquot TCGA-EJ-5509-01A-01D-1576-08) from TCGA case TCGA-EJ-5509, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.0 years (23,368 days).
Specimen TCGA-EJ-5509-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aab1892e-82b5-4799-8be4-de05414cf277.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5509-10A (Blood Derived Normal), aliquot TCGA-EJ-5509-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/674afac0-ae71-4c85-ba43-8a07af45b3ed

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 13, Silent 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.398T>G p.F133C | Missense Mutation (SNP) | VAF 64/233 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1057519967, COSV61653174, COSV61653874; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- C1QL2 | c.659G>C p.W220S | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV55606288, COSV55608022; called by muse, mutect2, varscan2
- CCDC88B | c.2646G>T p.K882N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV57265416; called by muse, mutect2
- CNGA3 | c.1348A>G p.T450A | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.019); catalogued as COSV55623243; called by muse, mutect2, varscan2
- DCDC1 | c.844C>G p.L282V | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.509); catalogued as COSV60837541, COSV60850320; called by muse, mutect2, varscan2
- ERCC3 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53426239; called by muse, mutect2
- FAM171B | c.2203A>T p.I735F | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.796); catalogued as COSV59001834; called by muse, mutect2, varscan2
- GABRG1 | c.363C>A p.D121E | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54951544, COSV54954244; called by muse, mutect2, varscan2
- GOT1L1 | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV56874980; called by muse, mutect2
- KDM6A | c.2960A>G p.K987R | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV65038513; called by muse, mutect2
- LAMB1 | c.4084G>A p.E1362K | Missense Mutation (SNP) | VAF 160/493 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.027); catalogued as COSV55963016; called by muse, mutect2, varscan2
- MYBPC3 | c.2177G>A p.R726H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.049); catalogued as rs397515953, COSV57023942, COSV57028482; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PALMD | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1487947192, COSV54163607; called by muse, mutect2, varscan2
- FHDC1 | c.690C>T p.G230= | Silent (SNP) | VAF 21/166 reads (13%) | catalogued as rs751935867, COSV52598757; called by muse, mutect2, varscan2
- MUC17 | c.12793T>C p.L4265= | Silent (SNP) | VAF 9/107 reads (8%) | catalogued as rs766534971, COSV60283725; called by muse, mutect2
- PRAMEF2 | c.1176C>T p.D392= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as rs199716299, COSV53573629; called by muse, varscan2
- PRXL2A | c.318C>T p.G106= | Silent (SNP) | VAF 37/134 reads (28%) | catalogued as rs761573557, COSV64690548; called by muse, mutect2, varscan2
- TMTC3 | c.1281T>C p.D427= | Silent (SNP) | VAF 10/224 reads (4%) | catalogued as COSV57123109; called by muse, mutect2
- ZNF831 | c.3474G>A p.T1158= | Silent (SNP) | VAF 33/130 reads (25%) | catalogued as rs767673212, COSV64038612; called by muse, mutect2, varscan2
